Somatic mutation profile of tumor specimen TARGET-10-PATLMA-03A (aliquot TARGET-10-PATLMA-03A-01D) from TARGET case TARGET-10-PATLMA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.5 years (3,115 days).
Specimen TARGET-10-PATLMA-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eefca9c9-80b0-4d1b-a75e-754b2549db83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATLMA-10A (Blood Derived Normal), aliquot TARGET-10-PATLMA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94435682-a62e-4c98-bf0f-1e5ce906156e

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Nonsense Mutation 4, Intron 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A5 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886067, CM960341, COSV60368653, COSV60371445; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 21/120 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AIM2 | c.1022A>C p.K341T | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV63701916; called by mutect2, varscan2
- ASCC3 | c.6409C>T p.R2137* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as rs760927168, COSV64973923, COSV64977816; called by muse, mutect2, varscan2
- CNOT3 | c.17A>C p.K6T | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55368257; called by muse, mutect2, varscan2
- EPB41L1 | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as rs781009046, COSV52444303; called by muse, mutect2, varscan2
- LYPD6 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs201660104, COSV61942263; called by muse, mutect2, varscan2
- MUC16 | c.20732C>A p.T6911N | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs371481946; called by muse, mutect2, varscan2
- NOTCH1 | c.7225C>T p.Q2409* | Nonsense Mutation (SNP) | VAF 41/167 reads (25%) | catalogued as COSV53030232; called by muse, mutect2, varscan2
- NOTCH1 | c.5033T>C p.L1678P | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53024869, COSV53029241; called by muse, mutect2, varscan2
- SLC1A4 | c.770C>A p.A257E | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52235446; called by muse, mutect2
- UTP14A | c.2161G>A p.V721I | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.53); catalogued as COSV64087860; called by mutect2, varscan2
- COPB1 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- DRICH1 | c.209-1G>T p.X70_splice | Splice Site (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- GABBR1 | c.2312G>T p.G771V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OBI1 | c.1557G>T p.M519I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, varscan2
- PAK1IP1 | c.230C>A p.A77D | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- PLCD4 | c.158C>A p.A53D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- PLCXD3 | c.621G>T p.W207C | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- RBM41 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- UBR5 | c.4993G>T p.D1665Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFYVE16 | c.1604C>A p.A535D | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.199); called by muse, mutect2
- LRRC49 | c.414G>A p.S138= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs200468894, COSV53014605; called by muse, mutect2, varscan2
- MAB21L1 | c.867G>T p.S289= | Silent (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- MROH2A | c.2355C>T p.C785= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs770274993; called by mutect2, varscan2
- MUC4 | c.6231C>T p.H2077= | Silent (SNP) | VAF 15/201 reads (7%) | catalogued as rs754819246, COSV62190874; called by muse, mutect2
- SEMA4C | c.417C>T p.Y139= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs370721332; called by muse, mutect2, varscan2
- ATP6AP2 | c.-36C>T | 5'UTR (SNP) | VAF 5/48 reads (10%) | catalogued as rs1057521485; ClinVar: likely benign; called by muse, mutect2
- RAB17 | c.435+569C>T | Intron (SNP) | VAF 18/70 reads (26%) | catalogued as rs149153125; called by muse, mutect2, varscan2
